Gene-level copy-number profile of tumor specimen ALCH-B066-TTP1-A from ALCHEMIST case ALCH-B066, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.4 years (25,366 days).
Specimen ALCH-B066-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c65d41f0-0dca-4cb5-8066-a25ec152688b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B066-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/541ac663-fb6e-43c9-b5f3-4786371b5341

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 179; copy number 1: 17,903; copy number 2: 37,770; copy number 3: 2,510; copy number 4: 413; copy number 5: 44; copy number 6: 32; copy number 7: 7; copy number 10: 5; copy number 11: 1; copy number 13: 28; copy number 22: 6; copy number 23: 7.

Homozygous deletions (total copy number 0; autosomes only): 153 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,812,962–52,835,729, 4 genes (within-gene range 0–1): ITIH4, AC006254.1, ITIH4-AS1, MUSTN1.
- chr5:150,113,839–150,558,211, 10 genes: PDGFRB, CDX1, SLC6A7, CAMK2A, ARSI, TCOF1, CD74, RPS14, NDST1-AS1, NDST1.
- chr7:5,592,816–5,606,655, 1 gene: FSCN1.
- chr8:12,628,476–12,676,389, 3 genes: RPS3AP35, AC068587.3, AC068587.1.
- chr9:21,802,636–23,438,700, 20 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:24,542,952–24,905,735, 3 genes: IZUMO3, AL353811.1, RMRPP5.
- chr9:61,190,003–61,789,426, 13 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P.
- chr9:61,898,805–61,911,022, 1 gene: FAM242E.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–1): AL357936.1.
- chr10:103,446,786–103,855,543, 13 genes (within-gene range 0–1): CALHM2, AL139339.2, AL139339.1, CALHM1, CALHM3, NEURL1-AS1, NEURL1, AL121929.1, AL121929.3, SH3PXD2A, AL121929.2, Y_RNA, SH3PXD2A-AS1.
- chr11:77,034,398–77,126,155, 3 genes (within-gene range 0–2): B3GNT6, CAPN5, OMP.
- chr12:124,337,181–124,337,242, 1 gene (within-gene range 0–1): MIR6880.
- chr13:111,316,184–111,344,249, 1 gene: TEX29.
- chr15:77,568,970–77,608,888, 1 gene: AC046168.2.
- chr16:89,873,570–89,938,761, 6 genes: TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:142,789–511,347, 11 genes (within-gene range 0–1): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2.
- chr17:2,689,386–3,037,741, 9 genes (within-gene range 0–1): CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:3,662,895–3,696,240, 5 genes: TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5.
- chr20:64,034,344–64,039,962, 1 gene (within-gene range 0–1): C20orf204.
- chr21:39,745,407–42,447,684, 46 genes: IGSF5, PCP4, DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1, YRDCP3, LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1, FAM3B, MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21, ZNF295-AS1, UMODL1, UMODL1-AS1, ABCG1, RNA5SP492, TFF3, TFF2, TFF1, TMPRSS3, UBASH3A, RNU6-1149P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 130 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:995,966–1,000,172, 2 genes, copy number 10: AL645608.7, HES4.
- chr2:64,631,621–64,751,005, 3 genes, copy number 5: SERTAD2, AC007365.1, RPS10P9.
- chr8:40,298,697–41,032,998, 6 genes, copy number 5: SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P.
- chr9:61,865,755–61,866,965, 1 gene, copy number 11: AL391987.4.
- chr9:64,462,819–64,466,498, 2 genes, copy number 5: CR769776.2, CYP4F25P.
- chr12:63,002,469–63,668,939, 9 genes, copy number 10–23 (within-gene range 3–23): AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2.
- chr12:63,651,627–63,651,930, 1 gene, copy number 10 (within-gene range 3–10): AC027667.1.
- chr12:69,901,918–71,118,247, 17 genes, copy number 5 (within-gene range 4–5): PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr14:36,061,026–41,904,549, 73 genes, copy number 5–22 (within-gene range 3–22) (broad region; genes not listed).
- chr14:99,397,748–99,480,889, 2 genes, copy number 5: SETD3, RNU6-91P.
- chr17:78,845,345–78,846,868, 2 genes, copy number 5: AC022966.2, RPL9P29.
- chr19:41,425,359–41,555,462, 11 genes, copy number 5–7 (within-gene range 3–7): AC011462.2, B3GNT8, DMAC2, Metazoa_SRP, ERICH4, PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1.
- chr19:41,551,568–41,552,274, 1 gene, copy number 7 (within-gene range 3–7): AC243960.10.

Autosomal genes at a single copy (total copy number 1): 15,585. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
